Somatic mutation profile of tumor specimen C3L-01287-01 (aliquot CPT0079400012) from CPTAC case C3L-01287, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage IV; Tumor grade: G4; Age at diagnosis: 60.4 years (22,045 days).
Specimen C3L-01287-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 48590652-8466-4533-95c0-14b781dcf135.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-01287-31 (Blood Derived Normal), aliquot CPT0080130002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/062b546a-cba9-44fa-828f-ec15f2c1df88

The open-access MAF lists 70 somatic variants for this specimen: 43 protein-altering or splice-affecting, 21 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 32, Silent 21, Nonsense Mutation 3, Frame Shift Del 3, Intron 3, Splice Site 2, Splice Region 1, In Frame Del 1, 3'Flank 1, Frame Shift Ins 1, 3'UTR 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BAP1 | c.277A>G p.T93A | Missense Mutation (SNP) | VAF 28/337 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs375129361, CM134949, COSV56236966; ClinVar: pathogenic; called by muse, mutect2
- CACNA1H | c.5384G>C p.G1795A | Missense Mutation (SNP) | VAF 14/172 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV52357665; called by muse, mutect2
- CDH16 | c.113C>G p.P38R | Missense Mutation (SNP) | VAF 20/202 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as rs751244459, COSV100233742; called by muse, mutect2
- CDH23 | c.8674C>T p.R2892W | Missense Mutation (SNP) | VAF 21/280 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.742); catalogued as rs1468886300, COSV56482903, COSV99819181; called by muse, mutect2
- EIF2D | c.948+2T>C p.X316_splice | Splice Site (SNP) | VAF 12/77 reads (16%) | catalogued as rs1553411032; called by muse, mutect2, varscan2
- F13A1 | c.2090G>A p.R697Q | Missense Mutation (SNP) | VAF 32/330 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs768408371, COSV53568965; called by muse, mutect2
- FKBP10 | c.766G>A p.V256I | Missense Mutation (SNP) | VAF 39/335 reads (12%) | SIFT tolerated (0.17); PolyPhen benign (0.113); catalogued as rs782380098; called by muse, mutect2, varscan2
- GRN | c.347C>A p.S116* | Nonsense Mutation (SNP) | VAF 25/142 reads (18%) | catalogued as CM100886; called by muse, mutect2, varscan2
- HGFAC | c.1808C>T p.A603V | Missense Mutation (SNP) | VAF 7/104 reads (7%) | SIFT tolerated (0.53); PolyPhen benign (0.003); catalogued as rs1444150955; called by muse, mutect2
- JCAD | c.268A>C p.T90P | Missense Mutation (SNP) | VAF 10/99 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.005); catalogued as COSV64759879; called by muse, mutect2, varscan2
- KRT86 | c.662G>A p.R221H | Missense Mutation (SNP) | VAF 26/552 reads (5%) | SIFT tolerated (0.29); PolyPhen benign (0.013); catalogued as rs531934335; called by muse, mutect2
- PDE2A | c.1315G>C p.E439Q | Missense Mutation (SNP) | VAF 13/218 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.208); catalogued as COSV57809356; called by muse, mutect2
- PXDNL | c.751G>T p.V251F | Missense Mutation (SNP) | VAF 8/154 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV62477807; called by muse, mutect2
- TENM1 | c.3967G>C p.D1323H | Missense Mutation (SNP) | VAF 5/65 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64443876; called by muse, mutect2
- TENT5D | c.244G>T p.D82Y | Missense Mutation (SNP) | VAF 22/159 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57638844; called by muse, mutect2, varscan2
- TMEM63C | c.1658C>A p.A553D | Missense Mutation (SNP) | VAF 14/170 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV100029889; called by muse, mutect2
- TUBGCP2 | c.1273G>A p.D425N | Missense Mutation (SNP) | VAF 37/183 reads (20%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.994); catalogued as rs761200870; called by muse, mutect2, varscan2
- USP6NL | c.2483T>A p.L828Q | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.973); catalogued as rs562437933; called by muse, mutect2, varscan2
- ZNF526 | c.1606C>T p.R536C | Missense Mutation (SNP) | VAF 53/564 reads (9%) | SIFT tolerated (0.12); PolyPhen benign (0.01); catalogued as rs147052277; called by muse, mutect2
- ACO1 | c.2423T>G p.L808R | Missense Mutation (SNP) | VAF 34/254 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ACSM6 | c.30G>C p.L10F | Missense Mutation (SNP) | VAF 8/130 reads (6%) | SIFT tolerated (0.11); PolyPhen benign (0.262); called by muse, mutect2
- ADCY9 | c.3617T>C p.I1206T | Missense Mutation (SNP) | VAF 44/230 reads (19%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- ALKBH7 | c.448G>A p.E150K | Missense Mutation (SNP) | VAF 39/205 reads (19%) | SIFT tolerated (0.2); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ASH1L | c.448G>A p.D150N | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.003); called by muse, mutect2
- CNTNAP4 | c.889G>T p.A297S | Missense Mutation (SNP) | VAF 22/336 reads (7%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.472); called by muse, mutect2
- COL14A1 | c.697G>T p.G233* | Nonsense Mutation (SNP) | VAF 14/137 reads (10%) | called by muse, mutect2
- DCBLD1 | c.1079G>A p.G360E | Missense Mutation (SNP) | VAF 8/95 reads (8%) | SIFT tolerated (0.53); PolyPhen probably damaging (0.984); called by muse, mutect2
- DPYD | c.2506G>C p.A836P | Missense Mutation (SNP) | VAF 37/275 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FAM149B1 | c.1075G>T p.V359F | Missense Mutation (SNP) | VAF 14/186 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.303); called by muse, mutect2
- GABBR2 | c.2197_2205del p.T733_T735del | In Frame Del (DEL) | VAF 59/272 reads (22%) | called by mutect2, pindel, varscan2
- HMCN1 | c.2211A>G p.K737= | Splice Region (SNP) | VAF 17/329 reads (5%) | called by muse, mutect2
- ILF2 | c.1061C>A p.S354* | Nonsense Mutation (SNP) | VAF 44/260 reads (17%) | called by muse, mutect2, varscan2
- KIF1B | c.1402C>T p.P468S (on ENST00000377086 / NM_001365952.1; = p.P422S on NM_015074.3) | Missense Mutation (SNP) | VAF 25/284 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0); called by muse, mutect2
- LDHB | c.838-2A>G p.X280_splice | Splice Site (SNP) | VAF 24/399 reads (6%) | called by muse, mutect2
- LUZP4 | c.604G>C p.E202Q | Missense Mutation (SNP) | VAF 15/107 reads (14%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.745); called by muse, varscan2
- MED1 | c.1400_1401dup p.D468Wfs*9 | Frame Shift Ins (INS) | VAF 34/324 reads (10%) | called by mutect2, pindel
- MGAM2 | c.1526A>G p.D509G | Missense Mutation (SNP) | VAF 5/83 reads (6%) | SIFT tolerated (0.28); PolyPhen benign (0.093); called by muse, mutect2
- RC3H1 | c.2490del p.D831Mfs*10 | Frame Shift Del (DEL) | VAF 30/129 reads (23%) | called by mutect2, pindel, varscan2
- SPEM2 | c.1494G>C p.E498D | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- TMEM270 | c.129C>A p.F43L | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- VHL | c.420_442del p.N141Cfs*25 | Frame Shift Del (DEL) | VAF 40/335 reads (12%) | called by mutect2, pindel
- ZMYM5 | c.621T>A p.S207R | Missense Mutation (SNP) | VAF 8/153 reads (5%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2
- ZNF219 | c.724_725del p.V243Pfs*12 | Frame Shift Del (DEL) | VAF 22/200 reads (11%) | called by mutect2, varscan2
- CACNA1H | c.5385C>T p.G1795= | Silent (SNP) | VAF 15/175 reads (9%) | catalogued as rs777171977; called by muse, mutect2
- COG5 | c.2100A>T p.S700= (on ENST00000347053 / NM_001379512.1; = p.S721= on NM_006348.5 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 24/306 reads (8%) | called by muse, mutect2
- CREBBP | c.1911A>G p.E637= | Silent (SNP) | VAF 29/465 reads (6%) | catalogued as COSV52124745; called by muse, mutect2
- FBLN2 | c.2691G>A p.R897= | Silent (SNP) | VAF 11/89 reads (12%) | catalogued as rs1464459092; called by muse, mutect2
- HLA-DMB | c.93G>A p.L31= | Silent (SNP) | VAF 7/54 reads (13%) | called by muse, varscan2
- KDM2B | c.1563G>A p.V521= | Silent (SNP) | VAF 33/328 reads (10%) | called by muse, mutect2, varscan2
- KDM5A | c.2100C>G p.L700= | Silent (SNP) | VAF 38/271 reads (14%) | called by muse, mutect2, varscan2
- MBD5 | c.3753A>G p.P1251= | Silent (SNP) | VAF 38/249 reads (15%) | called by muse, mutect2, varscan2
- MYBL1 | c.1233C>T p.V411= | Silent (SNP) | VAF 14/350 reads (4%) | catalogued as rs973843917; called by muse, mutect2
- NOD2 | c.381G>A p.S127= | Silent (SNP) | VAF 18/184 reads (10%) | catalogued as rs535978538; called by muse, mutect2
- NOTCH2 | c.6909C>T p.P2303= | Silent (SNP) | VAF 13/64 reads (20%) | catalogued as rs1311553574; called by muse, mutect2, varscan2
- PCDHB3 | c.1347C>T p.P449= | Silent (SNP) | VAF 93/607 reads (15%) | catalogued as rs782743177, COSV50569020, COSV50574942; called by muse, mutect2, varscan2
- PIWIL2 | c.2104C>A p.R702= | Silent (SNP) | VAF 10/92 reads (11%) | catalogued as COSV63254478; called by muse, varscan2
- PTPRZ1 | c.1605A>C p.S535= | Silent (SNP) | VAF 22/181 reads (12%) | called by muse, mutect2, varscan2
- RIN1 | c.390C>T p.S130= | Silent (SNP) | VAF 38/301 reads (13%) | called by muse, mutect2, varscan2
- SCLT1 | c.390C>G p.V130= | Silent (SNP) | VAF 13/180 reads (7%) | called by muse, mutect2
- STYXL2 | c.1302G>T p.L434= | Silent (SNP) | VAF 7/85 reads (8%) | called by muse, mutect2
- TNNT3 | c.654G>A p.L218= (on ENST00000397301 / NM_001367846.1; = p.L207= on NM_006757.4) | Silent (SNP) | VAF 85/580 reads (15%) | called by muse, mutect2, varscan2
- TRIM27 | c.1098C>T p.F366= | Silent (SNP) | VAF 40/238 reads (17%) | catalogued as rs1252217990, COSV65874203; called by muse, mutect2, varscan2
- XKR4 | c.483G>A p.V161= | Silent (SNP) | VAF 20/180 reads (11%) | called by muse, mutect2, varscan2
- ZNF724 | c.1476C>T p.H492= | Silent (SNP) | VAF 40/373 reads (11%) | called by muse, mutect2, varscan2
- LRP5L | n.298C>T | RNA (SNP) | VAF 49/329 reads (15%) | called by muse, mutect2, varscan2
- MBD2 | c.542+1616C>A | Intron (SNP) | VAF 15/75 reads (20%) | called by muse, mutect2, varscan2
- REEP6 | c.*259C>T | 3'UTR (SNP) | VAF 13/155 reads (8%) | called by muse, mutect2
- SREBF2 | c.2739-38A>G | Intron (SNP) | VAF 31/293 reads (11%) | catalogued as rs746778890; called by muse, mutect2, varscan2
- TPK1 | c.354+16A>G | Intron (SNP) | VAF 6/82 reads (7%) | called by muse, mutect2
- ZFPL1 | chr11:65090494 T>G | 3'Flank (SNP) | VAF 14/150 reads (9%) | called by muse, mutect2
